Somatic mutation profile of tumor specimen 0DYRQJ from CCDI case PBCSND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,366 days).
Specimen 0DYRQJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63c2cec1-4cd9-49ed-a79b-1f4efdd7ced3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYRPT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acd90269-4048-420b-8c10-eacd187ea044

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 321/984 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MAP2K1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 148/697 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs727504317, CM076269, COSV61068427, COSV61072298; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD12 | c.4507G>C p.E1503Q | Missense Mutation (SNP) | VAF 60/1317 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.092); catalogued as COSV100042196; called by muse, mutect2
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1554342786; called by mutect2, varscan2
- RBM25 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 78/550 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs143840737, COSV56199852; called by muse, mutect2, varscan2
- SIGLEC1 | c.4158G>A p.L1386= | Silent (SNP) | VAF 141/490 reads (29%) | called by muse, mutect2, varscan2
- TMEM185A | c.372G>A p.P124= | Silent (SNP) | VAF 180/1023 reads (18%) | called by muse, mutect2, varscan2
